MMRF case MMRF_2250 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/02008cce-b6fe-4922-ae6a-c76837df0509

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.4 years (26,087 days); ISS stage: II; Days to last known disease status: 851 days (2.3 years); Days to last follow up: 851 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -31 (ECOG 0): M Protein 3.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL; Immunoglobulin G 3.95 g/L; Immunoglobulin A 37.8 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3.38 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 29 g/L; Total Protein 9.6 g/dL; Glucose 6 mmol/L; C-Reactive Protein 0.29 mg/dL.
- Day 64 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.62 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 4.73 mmol/L.
- Day 134 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin A 0.84 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.83 mmol/L.
- Day 246 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 5.61 mmol/L.
- Day 308 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 7.54 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 5.72 mmol/L.
- Day 428 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 7.53 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 491: Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 7.34 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 591: Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 675: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 8.84 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 6.16 mmol/L.
- Day 797: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 6.74 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 851: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 7.89 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -31: Weight: 59 kg; Height: 148 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2250_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -31 days.
- Sample MMRF_2250_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -31 days.
